Somatic mutation profile of tumor specimen ALCH-B3GW-TTP1-A (aliquot ALCH-B3GW-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B3GW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,098 days).
Specimen ALCH-B3GW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4b9b365-55bc-451b-bb82-1ee47fcefa16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GW-NB1-A (Blood Derived Normal), aliquot ALCH-B3GW-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49ae974-0eb2-47b1-ae3e-17bbac5ec9f5

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 3, 5'Flank 2, Intron 2, 5'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 334/495 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen possibly damaging (0.853); catalogued as COSV59259218, COSV59259530, COSV59268643; called by muse, mutect2, varscan2
- CDKN3 | c.233T>C p.F78S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs776653682; called by muse, mutect2, varscan2
- CELSR1 | c.8912C>G p.S2971C | Missense Mutation (SNP) | VAF 25/747 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV53093123; called by muse, mutect2
- DGKZ | c.946C>T p.R316* (on ENST00000454345 / NM_001105540.2; = p.R128* on NM_003646.4) | Nonsense Mutation (SNP) | VAF 34/932 reads (4%) | catalogued as COSV58984127, COSV58989965; called by muse, mutect2
- DNAH17 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 143/906 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs775946342, COSV67755362; called by muse, mutect2, varscan2
- KCNAB2 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 27/696 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51235693; called by muse, mutect2
- MED23 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as rs759066563, COSV63432153; called by muse, varscan2
- NETO2 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs752644750; called by muse, mutect2, varscan2
- NPS | c.103T>C p.S35P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV67690779; called by muse, mutect2
- RB1 | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 14/119 reads (12%) | catalogued as CD040611, COSV57295141, COSV57300560; called by muse, mutect2, varscan2
- ROR1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.152); catalogued as rs1487255442; called by muse, mutect2
- TACO1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 22/554 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs995208099; called by muse, mutect2
- TLL2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 46/635 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs748097625; called by muse, mutect2
- TMEM161B | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99680643; called by muse, mutect2
- WDPCP | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs369786224, COSV99705262; ClinVar: uncertain significance; called by muse, mutect2
- ABCF1 | c.1663G>C p.E555Q (on ENST00000326195 / NM_001025091.2; = p.E517Q on NM_001090.3) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ANHX | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 26/770 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.431); called by muse, mutect2
- CSPG4 | c.3971G>T p.R1324L | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSRNP1 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 105/845 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DSCAM | c.3145T>G p.Y1049D | Missense Mutation (SNP) | VAF 223/1632 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DSG4 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAC2 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EPOP | c.881C>G p.P294R | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.883); called by muse, mutect2
- EPOP | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2
- FAM193A | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2
- GPR101 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ICE1 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 58/230 reads (25%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MTHFR | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 28/643 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, mutect2
- NRBP1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 82/643 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUMA1 | c.5536G>A p.A1846T | Missense Mutation (SNP) | VAF 172/1262 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCNX1 | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- RNF125 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- SALL2 | c.2020C>G p.L674V | Missense Mutation (SNP) | VAF 25/575 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMOC1 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TP53 | c.501_505del p.Q167Hfs*12 | Frame Shift Del (DEL) | VAF 81/540 reads (15%) | called by mutect2, pindel, varscan2
- TRAV9-1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); called by muse, mutect2
- TVP23B | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- WLS | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.146); called by muse, mutect2
- XAGE2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, varscan2
- BCL6 | c.63C>T p.N21= | Silent (SNP) | VAF 77/427 reads (18%) | catalogued as COSV51656487; called by muse, mutect2, varscan2
- ENC1 | c.1431C>T p.T477= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as rs1372681921; called by muse, mutect2
- H2AB1 | c.144G>C p.L48= | Silent (SNP) | VAF 70/2335 reads (3%) | catalogued as COSV57704117; called by muse, mutect2
- KDM5B | c.2823C>G p.L941= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- KIAA1671 | c.24C>A p.G8= | Silent (SNP) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- MET | c.3420C>T p.L1140= | Silent (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- NDST1 | c.2085C>G p.P695= | Silent (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- SHROOM3 | c.4059A>G p.P1353= | Silent (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- SPI1 | c.444C>T p.G148= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.270C>G p.L90= (on ENST00000394863 / NM_001042454.3; = p.L73= on NM_015927.4) | Silent (SNP) | VAF 24/880 reads (3%) | catalogued as COSV100691109; called by muse, mutect2
- TRA2A | c.747T>C p.Y249= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as rs752917047, COSV51716437; called by muse, mutect2, varscan2
- VPS4A | c.903G>A p.Q301= | Silent (SNP) | VAF 72/1105 reads (7%) | catalogued as rs953227769; called by muse, mutect2
- WDFY4 | c.1983C>G p.L661= | Silent (SNP) | VAF 99/834 reads (12%) | catalogued as rs760113841, COSV57444726; called by muse, mutect2, varscan2
- ZNF557 | c.15C>T p.V5= | Silent (SNP) | VAF 24/930 reads (3%) | called by muse, mutect2
- ANKH | c.-5G>A | 5'UTR (SNP) | VAF 154/1216 reads (13%) | catalogued as rs754988273; called by muse, mutect2
- CICP28 | chr7:56812136 G>A | 3'Flank (SNP) | VAF 69/237 reads (29%) | catalogued as rs1397826536; called by muse, mutect2, varscan2
- ENO1 | chr1:8878765 A>G | 5'Flank (SNP) | VAF 26/292 reads (9%) | catalogued as COSV99318588, COSV99318735, COSV99318759; called by muse, mutect2
- IGFN1 | c.1242-1264C>G | Intron (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- NTN5 | chr19:48673260 C>T | 5'Flank (SNP) | VAF 20/367 reads (5%) | catalogued as rs1274907854; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-51587G>C | Intron (SNP) | VAF 8/134 reads (6%) | catalogued as COSV101043099; called by muse, mutect2
